Somatic mutation profile of tumor specimen 0DC7ST from CCDI case PBBMBU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,592 days).
Specimen 0DC7ST: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78842586-06de-4d52-a67b-ebac14e70bbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC7T4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbfcc95a-432e-408f-a293-1b49dee142f5

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1110A>C p.L370F | Missense Mutation (SNP) | VAF 29/554 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs754168206, COSV50631152, COSV50657272; called by muse, mutect2
- NETO1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 14/498 reads (3%) | catalogued as rs1051379392, COSV55013594; called by muse, mutect2
- GABBR1 | c.1684T>A p.W562R | Missense Mutation (SNP) | VAF 260/872 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, varscan2
- GMPS | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 212/726 reads (29%) | called by muse, mutect2, varscan2
- OR2W1 | c.525T>A p.D175E | Missense Mutation (SNP) | VAF 43/774 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); called by muse, mutect2
- ALDH6A1 | c.-24G>A | 5'UTR (SNP) | VAF 28/490 reads (6%) | catalogued as rs760469054; called by muse, mutect2
